Somatic mutation profile of tumor specimen 0DU7AA from CCDI case PBCJVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 4.6 years (1,669 days).
Specimen 0DU7AA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb723a25-2055-447f-9cf7-0f819536f949.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU7A4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fff586f-1077-4006-a1ae-cc16b4bd6ab5

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 2, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 520/1693 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- GPR37 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 474/1446 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs1364183688, COSV58255450; called by muse, varscan2
- ITGA11 | c.2629G>A p.G877S | Missense Mutation (SNP) | VAF 485/1528 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs773471766; called by muse, varscan2
- PCCA | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 411/1876 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs376383373; ClinVar: uncertain significance; called by muse, varscan2
- RUNDC3B | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 516/1636 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.363); catalogued as rs750107326, COSV55949678, COSV55956462; called by muse, varscan2
- TMEM129 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 330/1073 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs759896680, COSV57558722; called by muse, varscan2
- VPS13A | c.3903G>A p.W1301* | Nonsense Mutation (SNP) | VAF 500/1609 reads (31%) | catalogued as COSV62426211; called by muse, varscan2
- MAP3K13 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 603/1726 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GRN | c.1701C>T p.A567= | Silent (SNP) | VAF 350/1138 reads (31%) | catalogued as rs752764522; called by muse, varscan2
- SENP3 | c.1449G>A p.S483= | Silent (SNP) | VAF 384/1272 reads (30%) | catalogued as rs367680093; called by muse, varscan2
- ABCD2 | c.-85T>A | 5'UTR (SNP) | VAF 173/623 reads (28%) | called by muse, varscan2
- BBS1 | c.831-35C>A | Intron (SNP) | VAF 202/930 reads (22%) | called by muse, varscan2
- SLC43A3 | c.-61G>A | 5'UTR (SNP) | VAF 104/384 reads (27%) | catalogued as rs1319256903, COSV100725144; called by muse, varscan2
